Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAC8, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAC8-01A (Primary Tumor).

[page 1 of 3]
IGD-0-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0
QD 5/19/14

CLINICAL DIAGNOSIS: HCC

Specimen : Liver

Gross Photo : 1

GROSS:

1. Specimen:

Liver: 26.0 x 19.0 x 10.0 cm, 1264.0 gm, unfixed

Gallbladder:

8.0 cm in length ,3.5 cm in width, and 2.0 mm in thickness, unfixed

2. Tumor location: right lobe

Tumor number: one

Tumor size: 12.5 x 9.0 x 15.0 cm

3. Satellite nodule: no

4. Gross type

HCC: vaguely nodular

5. Tumor necrosis: no

6. Hemorrhage/peliosis: no

7. Portal vein invasion: no

8. Bile duct invasion: no

Gross photo present.

Blocks

, tumor mass x 9
, resection margin x 1
, non-tumorous liver parenchyme x 1
, gallbladder x 2

MICROSCOPIC:

1. Hepatocellular carcinoma: yes

1-1. Differentiation

The worst differentiation III

The major differentiation III

1-2. Histologic type: trabecular

1-3. Cell type: hepatic

1-4. Fatty change: no

2. Cholangiocarcinoma: no

3. Combined hepatocellular and cholangiocarcinoma: no

4. Fibrous capsule formation: partial capsule

5. Capsular infiltration: yes

[page 2 of 3]
6. Septum formation: no
7. Surgical resection margin invasion: no, margin of the clearance (2.0 cm)
8. Serosal invasion: no
9. Portal vein invasion: no
10. Bile duct invasion: no
11. Hepatic vein invasion: no
12. Hepatic artery invasion: no
13. Microvessel invasion: yes
14. Intrahepatic metastasis: no
15. Multicentric occurrence: no

Non-tumor liver pathology

1. Chronic hepatitis: yes
- 1-1. Etiology: HBV
- 1-2. Grade, lobular: minimal
- 1-3. Grade, portoperiportal: mild
- 1-4. Stage (fibrosis): periportal
- 1-5. Cirrhosis: no
2. Dysplastic nodule: no
3. Ductal epithelial dysplasia: no
4. Other liver diseases: no

SPECIAL STAIN:

Trichrome: positive (stage 2)

NOT reported. Gross:

Liver, needle, hepatocellular carcinoma

Liver, ectomy, hepatocellular carcinoma
T56000, P10, M81703
Gallbladder, ectomy, chronic cholecystitis
T57000, P10, M43005

DIAGNOSIS:

Liver, right lobe, lobectomy:
Hepatocellular carcinoma, moderately differentiated
Gallbladder, cholecystectomy:
Chronic cholecystitis

[page 3 of 3]
NOTE: Recommend to order immunohistochemistry (hepatocyte, CK7, and CK19) and special stain (mucicarmine) for block T1.

Suggestion :

Source: NCI Genomic Data Commons file aecefc41-f621-41a3-b534-e2be03dd9fbd (TCGA-DD-AAC8.2751F570-A1CE-4F6A-98CD-56C8B31AB0FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).